Somatic mutation profile of tumor specimen TCGA-C5-A8XJ-01A (aliquot TCGA-C5-A8XJ-01A-11D-A37N-09) from TCGA case TCGA-C5-A8XJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Age at diagnosis: 74.2 years (27,087 days).
Specimen TCGA-C5-A8XJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e000112-eff5-4781-8e20-74b71e88a2a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A8XJ-10A (Blood Derived Normal), aliquot TCGA-C5-A8XJ-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/207a4fb4-ccfd-4382-91a3-fc2374bd15c3

The open-access MAF lists 365 somatic variants for this specimen: 257 protein-altering or splice-affecting, 101 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 225, Silent 101, Nonsense Mutation 20, Intron 4, Splice Region 4, In Frame Del 2, Splice Site 2, Frame Shift Del 2, 5'UTR 1, RNA 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 40/206 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs1555950665, COSV101302370, COSV67863415; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 24/85 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC12 | c.2121C>G p.F707L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs762185830, COSV100252339; called by muse, mutect2, varscan2
- ABHD2 | c.720G>A p.L240= | Splice Region (SNP) | VAF 11/28 reads (39%) | catalogued as COSV61776513; called by muse, mutect2, varscan2
- AC100868.1 | c.1657G>A p.D553N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV51843219; called by muse, mutect2, varscan2
- ACSM5 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.263); catalogued as rs530105948, COSV100088604, COSV59369492; called by muse, mutect2, varscan2
- ADAM15 | c.1973G>A p.R658Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.029); catalogued as rs769479538, COSV99664824; called by muse, mutect2, varscan2
- ADCY8 | c.3214G>A p.E1072K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.579); catalogued as COSV53922880, COSV99653381; called by mutect2, varscan2
- AGO1 | c.2509C>T p.P837S | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.027); catalogued as COSV100940781; called by muse, mutect2, varscan2
- ANKZF1 | c.1770G>C p.K590N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as rs750701800; called by muse, mutect2
- ANXA9 | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.266); catalogued as COSV100929078; called by muse, mutect2, varscan2
- AP3D1 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.065); catalogued as COSV100642480; called by muse, mutect2, varscan2
- ATF7-NPFF | c.1313G>C p.G438A | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.999); catalogued as COSV99908434; called by muse, mutect2, varscan2
- BAZ1A | c.946G>C p.E316Q | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV100701106; called by muse, mutect2, varscan2
- BCAT1 | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.074); catalogued as COSV99678302; called by muse, mutect2, varscan2
- BIRC6 | c.13539G>C p.M4513I | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV101428005; called by muse, mutect2, varscan2
- BOD1L1 | c.6346G>C p.E2116Q | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99238826; called by muse, mutect2, varscan2
- C1QTNF9 | c.271C>G p.Q91E | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.024); catalogued as rs1327351368, COSV100129827; called by muse, mutect2, varscan2
- C1QTNF9B | c.271C>G p.Q91E | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as rs1279207892; called by muse, mutect2
- CACNA1F | c.1237G>C p.E413Q | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.201); catalogued as COSV100544537, COSV59902763; called by muse, mutect2, varscan2
- CACNA2D4 | c.3307G>C p.E1103Q | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV99765289; called by muse, mutect2, varscan2
- CAPN9 | c.168C>G p.F56L | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.685); catalogued as COSV99680115; called by muse, mutect2, varscan2
- CARMIL3 | c.2885C>G p.S962C | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.423); catalogued as COSV100549097, COSV100549431; called by muse, mutect2, varscan2
- CASS4 | c.2115G>C p.Q705H | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.022); catalogued as COSV100824587; called by muse, mutect2, varscan2
- CBFA2T2 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV100656210, COSV100656447; called by mutect2, varscan2
- CCDC114 | c.648G>C p.Q216H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV100196502; called by muse, mutect2, varscan2
- CCDC17 | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as COSV99322055; called by muse, mutect2, varscan2
- CCDC71 | c.1174A>G p.R392G | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.387); catalogued as COSV58910520; called by muse, mutect2, varscan2
- CCDC89 | c.1043C>G p.S348C | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as COSV57033846; called by muse, mutect2, varscan2
- CEP112 | c.2626G>T p.E876* (on ENST00000392769 / NM_001353127.1; = p.E132* on NM_001037325.3) | Nonsense Mutation (SNP) | VAF 12/83 reads (14%) | catalogued as COSV100438983; called by muse, mutect2, varscan2
- CFAP54 | c.7888C>T p.Q2630* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as COSV61573061; called by muse, mutect2, varscan2
- CHAD | c.135G>T p.K45N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.543); catalogued as COSV99366101; called by muse, mutect2, varscan2
- CLGN | c.1074G>A p.W358* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100346462; called by muse, mutect2, varscan2
- CNTN1 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs745456807, COSV61635904; called by muse, mutect2, varscan2
- COL16A1 | c.2114C>G p.S705* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as COSV54715429, COSV99593828; called by muse, mutect2, varscan2
- COL4A5 | c.2773G>A p.D925N | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV60355654; called by muse, mutect2, varscan2
- CPN1 | c.8A>T p.D3V | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV100962577; called by muse, mutect2, varscan2
- CPN1 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100962578; called by muse, mutect2, varscan2
- CRHR1 | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV99523402; called by muse, mutect2
- CTDP1 | c.1357G>C p.D453H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV99310262; called by muse, mutect2, varscan2
- CUL9 | c.6427G>T p.E2143* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as COSV99335062; called by muse, mutect2, varscan2
- CYP2U1 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs748485159, COSV100256637; called by muse, mutect2, varscan2
- DCAF12L1 | c.1109G>A p.G370D | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100948160; called by muse, mutect2, varscan2
- DENND2A | c.2641G>A p.E881K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as rs533169195, COSV99325724; called by muse, mutect2, varscan2
- DENND6A | c.1141C>G p.P381A | Missense Mutation (SNP) | VAF 59/88 reads (67%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV100231371; called by muse, mutect2, varscan2
- DERL3 | c.291C>A p.F97L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV51954647, COSV99320177; called by muse, mutect2, varscan2
- DHX35 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as rs1243578098, COSV52669620; called by muse, mutect2, varscan2
- DHX58 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV52426728, COSV99288096; called by muse, mutect2, varscan2
- DIP2B | c.4000C>T p.P1334S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV56581691, COSV56590661; called by muse, mutect2, varscan2
- DMD | c.2251C>T p.R751W | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs373475448, COSV55904302; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH3 | c.1037C>T p.T346M | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.214); catalogued as rs372982554; called by muse, mutect2, varscan2
- DSCAML1 | c.1163T>G p.I388S (on ENST00000321322; = p.I328S on NM_020693.4) | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.46); catalogued as COSV100355205, COSV58396703; called by muse, mutect2, varscan2
- ECT2L | c.1907G>A p.R636K | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100871817; called by muse, mutect2, varscan2
- EP300 | c.3831G>C p.K1277N | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54337214, COSV99607830; called by muse, varscan2
- EPHA6 | c.2572C>T p.R858W (on ENST00000389672 / NM_001080448.3; = p.R250W on NM_173655.4) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369106551, COSV67597375; called by muse, mutect2, varscan2
- EPS15 | c.1239G>C p.K413N | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100869455; called by muse, mutect2, varscan2
- ESR1 | c.894C>G p.I298M | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.101); catalogued as COSV99238323; called by muse, mutect2, varscan2
- EXOC3 | c.264G>C p.Q88H | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as COSV100155213; called by muse, mutect2, varscan2
- EXTL2 | c.369C>G p.F123L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.217); catalogued as COSV100921092; called by muse, mutect2, varscan2
- FABP9 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV100986929, COSV66911626; called by muse, mutect2, varscan2
- FAM111B | c.1797G>T p.L599F | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV100639250, COSV59111936; called by muse, mutect2, varscan2
- FAM170A | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100088844; called by muse, mutect2, varscan2
- FAM47C | c.1440G>C p.E480D | Missense Mutation (SNP) | VAF 57/303 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.333); catalogued as COSV100792390; called by muse, mutect2, varscan2
- FAT4 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1353199749, COSV101272158; called by muse, mutect2, varscan2
- FBH1 | c.169C>G p.Q57E (on ENST00000362091 / NM_178150.3; = p.Q108E on NM_032807.4) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100758660; called by muse, mutect2, varscan2
- FBXO21 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100401647, COSV57975377; called by muse, mutect2, varscan2
- FHOD1 | c.3361C>T p.R1121C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1260057612, COSV99263939; called by muse, mutect2, varscan2
- FLNA | c.7536C>G p.F2512L (on ENST00000369850 / NM_001110556.2; = p.F2504L on NM_001456.3) | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV100774435; called by muse, varscan2
- FRMD7 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100048778; called by muse, mutect2, varscan2
- FRMPD3 | c.4160C>T p.S1387F | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99345901; called by muse, mutect2, varscan2
- FUCA1 | c.449C>G p.S150C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100991265; called by muse, mutect2, varscan2
- G6PD | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as CM910162, COSV100854972, COSV100855133; called by muse, varscan2
- GART | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV100738106, COSV63113730; called by muse, mutect2, varscan2
- GBP4 | c.1894G>C p.G632R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.048); catalogued as COSV100864332; called by muse, mutect2, varscan2
- GBP4 | c.1783G>C p.E595Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as COSV100864333; called by muse, mutect2, varscan2
- GFPT1 | c.661C>G p.H221D | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.101); catalogued as COSV100622725; called by muse, mutect2, varscan2
- GIT1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1449649255, COSV56612839; called by muse, mutect2, varscan2
- GPALPP1 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1371384543, COSV100689163, COSV62705805; called by muse, mutect2, varscan2
- GPC1 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.566); catalogued as rs937679330, COSV99882707, COSV99883229; called by muse, mutect2, varscan2
- GPX4 | c.218G>A p.Sec73* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100684236; called by muse, mutect2, varscan2
- GRHL2 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV99306372; called by muse, mutect2, varscan2
- GSTCD | c.731C>G p.S244* (on ENST00000360505 / NM_001031720.3; = p.S157* on NM_024751.3) | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100853794, COSV100853867; called by mutect2, varscan2
- HAO1 | c.1050G>C p.Q350H | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV66491687, COSV66494054, COSV99060335; called by muse, mutect2, varscan2
- HBS1L | c.393G>C p.K131N | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.16); catalogued as COSV100122025; called by muse, mutect2, varscan2
- HECTD2 | c.1782C>G p.I594M | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); catalogued as COSV99978332; called by mutect2, varscan2
- HIVEP1 | c.5651C>G p.S1884C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101044946; called by muse, mutect2, varscan2
- HJURP | c.1958C>G p.S653* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as COSV100982569; called by muse, mutect2, varscan2
- HNRNPH1 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV100270418; called by muse, mutect2, varscan2
- HOXB13 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs546307661, COSV51706631, COSV99285134; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IMPG1 | c.160A>C p.M54L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100886245; called by muse, mutect2, varscan2
- INPP5A | c.328C>T p.L110F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV61247898; called by muse, mutect2, varscan2
- INPP5J | c.1205C>G p.S402C | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.339); catalogued as COSV100459236; called by muse, varscan2
- IQCE | c.501G>A p.M167I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100383278; called by muse, mutect2, varscan2
- IRAK3 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99706017; called by muse, mutect2, varscan2
- ITGB4 | c.3091G>A p.G1031S | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1484207057, COSV99563624; called by muse, mutect2, varscan2
- ITGB8 | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99750925; called by muse, mutect2, varscan2
- JAK3 | c.3222G>A p.M1074I | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV101512895; called by muse, mutect2, varscan2
- KALRN | c.2728G>C p.E910Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1181997211, COSV53766122, COSV99562885; called by muse, mutect2, varscan2
- KASH5 | c.847G>C p.E283Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV71358002; called by muse, mutect2, varscan2
- KCNT1 | c.486C>G p.V162= (on ENST00000488444; = p.V181= on NM_020822.3) | Splice Region (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99705296; called by muse, mutect2, varscan2
- KIAA1522 | c.1124C>T p.S375F (on ENST00000373480 / NM_001198972.2; = p.S434F on NM_020888.3) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as COSV99614343; called by muse, mutect2, varscan2
- KLHL32 | c.1055G>A p.G352E | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65116080; called by muse, mutect2, varscan2
- KMT2A | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100628309; called by muse, varscan2
- KMT2A | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as rs1555035714, COSV63288980, COSV63291142; called by muse, varscan2
- KMT2C | c.8152G>C p.E2718Q | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV51394690, COSV51452543, COSV51519886; called by muse, mutect2, varscan2
- L2HGDH | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs767037296, COSV55556588, COSV55556772; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMA5 | c.10428C>A p.S3476R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99438729; called by muse, mutect2
- LAMA5 | c.4694C>T p.S1565F | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as rs781125987, COSV99438730; called by muse, varscan2
- LAT | c.396G>A p.W132* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as COSV100208972; called by muse, mutect2, varscan2
- LMO7 | c.3593C>T p.P1198L (on ENST00000357063; = p.P879L on NM_005358.5) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs776852274, COSV100412200, COSV58541578; called by muse, mutect2, varscan2
- LRBA | c.7636G>C p.A2546P | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100841139; called by muse, mutect2, varscan2
- LRCH3 | c.677C>G p.S226* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100605022, COSV100605311; called by muse, mutect2, varscan2
- LRP2 | c.13951G>T p.E4651* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV55569686, COSV99787185; called by muse, mutect2, varscan2
- LTN1 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100797923; called by muse, mutect2, varscan2
- MAB21L4 | c.598C>T p.H200Y (on ENST00000388934 / NM_001085437.3; = p.H32Y on NM_024861.4) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as COSV56745222; called by muse, mutect2, varscan2
- MAGEL2 | c.2230G>A p.A744T | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as rs764011034, COSV58565968; called by muse, mutect2, varscan2
- MARF1 | c.2131C>T p.R711* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as COSV100705687; called by muse, mutect2, varscan2
- MAST4 | c.6250G>A p.E2084K (on ENST00000403625 / NM_001164664.2; = p.E1895K on NM_015183.3) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.024); catalogued as rs554102328, COSV55121883; called by muse, varscan2
- MED12 | c.3412C>T p.R1138W | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61339953, COSV61342433; called by muse, mutect2, varscan2
- MEI1 | c.3059C>G p.S1020C | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV100299736; called by muse, mutect2
- MEOX2 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.161); catalogued as COSV100012020; called by muse, mutect2, varscan2
- MICAL3 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs1348462333, COSV99260567; called by muse, mutect2, varscan2
- MLLT10 | c.93G>C p.E31D | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs1363341174, COSV100307704, COSV56991184; called by muse, mutect2, varscan2
- MPDZ | c.3908C>T p.S1303L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV100056370; called by muse, mutect2, varscan2
- MRTFA | c.2944G>A p.D982N | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV99960233; called by muse, mutect2
- MTM1 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as rs398123269, COSV100080280; ClinVar: uncertain significance; called by muse, varscan2
- MX2 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.545); catalogued as rs367788793; called by muse, mutect2, varscan2
- MXRA5 | c.3289G>A p.D1097N | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99476157; called by muse, mutect2, varscan2
- MYH14 | c.2314G>C p.E772Q | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.373); catalogued as COSV99222149, COSV99223342; called by muse, mutect2, varscan2
- MYH2 | c.2460C>G p.I820M | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV55440710; called by muse, mutect2, varscan2
- MYH8 | c.5719G>C p.E1907Q | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV101238311; called by muse, mutect2, varscan2
- MYL5 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as rs1233430076, COSV100448393; called by muse, mutect2, varscan2
- MYO1F | c.2509G>A p.D837N | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV100596467; called by muse, mutect2, varscan2
- MYO3B | c.3485C>T p.S1162F | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV100509571; called by muse, varscan2
- MYO7A | c.2160G>C p.Q720H | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV101289080; called by muse, varscan2
- MYPN | c.2495C>G p.S832C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV100589716; called by muse, mutect2, varscan2
- NAB1 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.018); catalogued as rs954973214, COSV61609489; called by muse, mutect2, varscan2
- NAV3 | c.5551C>T p.R1851W (on ENST00000397909 / NM_001024383.2; = p.R1829W on NM_014903.6) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1309200135, COSV57116840; called by muse, mutect2, varscan2
- NCF1 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as COSV99194254; called by mutect2, varscan2
- NCF2 | c.1363C>T p.Q455* | Nonsense Mutation (SNP) | VAF 24/71 reads (34%) | catalogued as COSV100838868; called by muse, mutect2, varscan2
- NLRP9 | c.1143G>C p.Q381H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.396); catalogued as COSV100242779; called by muse, mutect2, varscan2
- NONO | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99338675; called by muse, mutect2, varscan2
- NOTCH1 | c.1650C>A p.Y550* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as COSV104374504, COSV53099012, COSV53109473; called by muse, mutect2, varscan2
- NR1H2 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.111); catalogued as rs764103032; called by muse, varscan2
- NR2E3 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs528986571, COSV100489286; called by muse, mutect2, varscan2
- NSD1 | c.1393G>C p.E465Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.068); catalogued as rs1373466948, COSV100728603; called by muse, mutect2, varscan2
- NUP93 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV100359831, COSV100360032; called by muse, mutect2, varscan2
- ODR4 | c.1131G>A p.M377I | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.098); catalogued as COSV99834208; called by muse, mutect2, varscan2
- OPHN1 | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100830173, COSV62783351; called by muse, mutect2, varscan2
- OR4A16 | c.240G>A p.M80I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs781251889, COSV100125082, COSV100125094; called by muse, mutect2, varscan2
- OR8J3 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100040671, COSV56882319; called by muse, mutect2
- ORC2 | c.1006C>A p.H336N | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV99309465; called by muse, mutect2, varscan2
- PABPC5 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.019); catalogued as rs779583126, COSV100442201; called by muse, varscan2
- PHF20 | c.2845C>T p.L949F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100926539; called by muse, mutect2, varscan2
- PI4KA | c.5512G>A p.D1838N | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs760261849, COSV99745092; called by muse, mutect2, varscan2
- PIK3CA | c.2598G>C p.L866F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.343); catalogued as COSV55887127; called by muse, mutect2, varscan2
- PKM | c.1350C>G p.I450M | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.712); catalogued as COSV100064628; called by muse, varscan2
- PMM1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.989); catalogued as rs376315549, COSV99348086; called by muse, mutect2, varscan2
- PMS1 | c.1747C>G p.Q583E | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.519); catalogued as rs1559308226, COSV100575523; called by muse, mutect2, varscan2
- PNCK | c.80C>T p.S27F (on ENST00000340888 / NM_001366975.1; = p.S110F on NM_001039582.3) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100562239; called by muse, mutect2, varscan2
- POGK | c.1376G>C p.G459A | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV100902437; called by muse, mutect2, varscan2
- PPFIA2 | c.3613G>A p.E1205K | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.124); catalogued as COSV61041182; called by muse, mutect2, varscan2
- PPFIBP2 | c.961C>T p.Q321* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as rs749845413, COSV100206243; called by muse, varscan2
- PRAM1 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs1166143587, COSV99725366; called by muse, mutect2, varscan2
- PSD | c.2342G>A p.R781Q | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1348883108, COSV99192267; called by muse, mutect2, varscan2
- PSG1 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.474); catalogued as COSV54953133, COSV99739244; called by muse, mutect2, varscan2
- PSMB9 | c.311G>A p.R104K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.85); PolyPhen benign (0.006); catalogued as COSV100841136; called by muse, mutect2, varscan2
- PSMD2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100031616; called by muse, mutect2, varscan2
- PTPRD | c.2629G>C p.E877Q | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.099); catalogued as COSV100643943, COSV61930135; called by muse, mutect2, varscan2
- QPCT | c.826C>T p.H276Y | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.191); catalogued as rs762938073, COSV100621545; called by muse, mutect2, varscan2
- R3HDML | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373660156; called by muse, mutect2, varscan2
- RANBP2 | c.81G>A p.M27I | Missense Mutation (SNP) | VAF 85/252 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV51697734, COSV51708779; called by muse, mutect2, varscan2
- RASGRP4 | c.1233C>T p.L411= | Splice Region (SNP) | VAF 22/51 reads (43%) | catalogued as COSV99384897; called by muse, mutect2, varscan2
- RASL12 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.145); catalogued as COSV99584810; called by muse, mutect2, varscan2
- RB1CC1 | c.3784G>C p.E1262Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV99209129; called by muse, mutect2, varscan2
- RB1CC1 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV99209158; called by muse, mutect2, varscan2
- RBBP9 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61500419; called by muse, mutect2, varscan2
- RHOBTB3 | c.1371G>C p.K457N | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV101183158; called by muse, mutect2, varscan2
- RHOT1 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as COSV100447004; called by muse, mutect2, varscan2
- RPH3AL | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 46/80 reads (58%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs528287300, COSV100046629; called by muse, mutect2, varscan2
- RPL19 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV99841392; called by muse, mutect2, varscan2
- RPRM | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.74); catalogued as COSV100371523; called by muse, mutect2, varscan2
- RPS6KA6 | c.1993C>T p.H665Y | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.129); catalogued as COSV99424381; called by muse, mutect2, varscan2
- RSBN1L | c.829C>G p.Q277E | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100615956; called by muse, mutect2, varscan2
- SAMHD1 | c.486C>G p.H162Q | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99483890; called by muse, mutect2, varscan2
- SBSPON | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs778810907, COSV99817398; called by muse, mutect2, varscan2
- SCLT1 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99827799; called by muse, varscan2
- SCLT1 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs778310681, COSV99827800; called by muse, varscan2
- SEC11C | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as COSV55311660; called by muse, mutect2, varscan2
- SH3D19 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); catalogued as rs150966759, COSV100455582; called by muse, varscan2
- SLC25A5 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as COSV100510215; called by muse, mutect2, varscan2
- SLC2A13 | c.1125C>G p.F375L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV99786192, COSV99786195; called by muse, mutect2, varscan2
- SLC35B1 | c.576G>A p.M192I (on ENST00000649906; = p.M155I on NM_005827.4) | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV99539402; called by muse, mutect2, varscan2
- SLC39A7 | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100807629; called by muse, mutect2
- SOGA1 | c.3491C>T p.S1164F | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV99413181; called by muse, mutect2, varscan2
- SPATA13 | c.429G>A p.L143= | Splice Region (SNP) | VAF 15/36 reads (42%) | catalogued as rs747419766, COSV100542083; called by muse, mutect2, varscan2
- SPHKAP | c.1615C>G p.Q539E | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV100763856; called by muse, mutect2
- SPRY3 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100249249; called by muse, mutect2, varscan2
- SPTY2D1 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0.197); catalogued as COSV60473701; called by muse, mutect2, varscan2
- SSH1 | c.2989G>A p.D997N | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.153); catalogued as COSV100425394; called by muse, mutect2, varscan2
- SSX2IP | c.92C>G p.S31* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100642517; called by muse, mutect2, varscan2
- STARD8 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV52933744, COSV99366456; called by muse, mutect2, varscan2
- STAT2 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.953); catalogued as COSV100028702; called by muse, mutect2, varscan2
- STK11 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as rs1473347455, COSV100479841, COSV58822317; called by muse, varscan2
- STRADA | c.328G>C p.E110Q (on ENST00000336174 / NM_001363786.1; = p.E73Q on NM_153335.6) | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); catalogued as COSV99834973; called by muse, mutect2
- SUPT5H | c.1119C>G p.F373L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV63238623, COSV63238781, COSV63243052; called by muse, mutect2, varscan2
- SYT12 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as COSV101210835; called by muse, mutect2, varscan2
- TAFA5 | c.84C>G p.I28M | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.233); catalogued as COSV100385589; called by muse, mutect2, varscan2
- TCOF1 | c.617C>G p.S206C | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100077065; called by muse, mutect2, varscan2
- TDRD3 | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 48/83 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as COSV99539949; called by muse, mutect2, varscan2
- TEX11 | c.661C>G p.L221V (on ENST00000344304; = p.L206V on NM_031276.3) | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100721460; called by muse, mutect2, varscan2
- TEX55 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.818); catalogued as COSV55212892; called by muse, mutect2, varscan2
- TFB2M | c.759C>G p.I253M | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV100830433; called by muse, mutect2, varscan2
- THAP7 | c.392G>C p.R131P | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs755408769, COSV53145783, COSV99301459; called by muse, mutect2, varscan2
- TIMELESS | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as COSV57511437; called by muse, mutect2, varscan2
- TMEM131 | c.2113A>G p.I705V | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.5); catalogued as COSV51772769; called by muse, mutect2, varscan2
- TMEM19 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs185566519, COSV56999935, COSV99876851; called by muse, mutect2, varscan2
- TMEM74B | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1307181615, COSV101121961; called by muse, mutect2, varscan2
- TMF1 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.05); catalogued as COSV101275414; called by muse, mutect2, varscan2
- TNFAIP3 | c.1094G>A p.R365K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs1218573061, COSV99396474; called by muse, varscan2
- TP53BP1 | c.2630C>G p.S877* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV55496499; called by muse, mutect2, varscan2
- TRAPPC2L | c.207-1G>A p.X69_splice | Splice Site (SNP) | VAF 13/35 reads (37%) | catalogued as COSV99243001; called by muse, mutect2, varscan2
- TRPA1 | c.2029G>C p.D677H | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as COSV100083566; called by muse, mutect2
- TRPC7 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.275); catalogued as COSV61457859; called by muse, mutect2, varscan2
- TRPM1 | c.4804G>A p.E1602K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV99855581; called by muse, mutect2, varscan2
- TTLL7 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV53083702; called by muse, varscan2
- TXLNG | c.1161G>C p.K387N | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100417838; called by muse, mutect2, varscan2
- UBE2D3 | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); catalogued as COSV100414875; called by muse, varscan2
- UNC13B | c.4066G>C p.D1356H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101036403; called by muse, mutect2
- UNC5D | c.1211G>A p.R404K | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.97); catalogued as COSV99773465; called by muse, mutect2, varscan2
- UNC79 | c.3024G>T p.L1008F (on ENST00000393151 / NM_001346218.2; = p.L831F on NM_020818.5) | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.853); catalogued as COSV99826494; called by muse, varscan2
- VDR | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.419); catalogued as COSV99968613; called by muse, mutect2, varscan2
- WASHC5 | c.1075A>T p.I359F | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as COSV100572682; called by muse, mutect2, varscan2
- WNK3 | c.1526C>G p.S509C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV100671016; called by muse, mutect2
- YLPM1 | c.3017G>A p.R1006K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.013); catalogued as COSV99459024; called by muse, mutect2, varscan2
- YTHDF1 | c.412C>G p.Q138E | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.798); catalogued as COSV64832693; called by muse, mutect2, varscan2
- ZCCHC14 | c.2123C>T p.S708F (on ENST00000268616; = p.S845F on NM_015144.3) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs1422422128, COSV99233612; called by muse, mutect2, varscan2
- ZFAND2A | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100335851; called by muse, mutect2, varscan2
- ZNF20 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.061); catalogued as COSV100502912; called by muse, mutect2, varscan2
- ZNF254 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 19/49 reads (39%) | catalogued as rs578183124, COSV100741551; called by muse, mutect2, varscan2
- ZNF354A | c.1772C>T p.S591L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100234392; called by muse, mutect2, varscan2
- ZNF449 | c.1196G>A p.R399K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as COSV100202886, COSV59346931; called by muse, mutect2, varscan2
- ZNF483 | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 20/47 reads (43%) | catalogued as COSV100492717; called by muse, mutect2, varscan2
- ZNF546 | c.2276G>A p.R759H | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.886); catalogued as rs760099860, COSV61257158; called by muse, mutect2, varscan2
- ZNF596 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.137); catalogued as COSV57655497; called by muse, mutect2, varscan2
- ZNF799 | c.1723C>A p.L575I | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.599); catalogued as COSV101345248; called by muse, mutect2, varscan2
- ZSWIM8 | c.2670G>T p.K890N | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101289845, COSV101289885; called by muse, mutect2, varscan2
- CYP2B6 | c.285_287delinsTT p.S96Lfs*18 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | called by pindel, varscan2*
- DDX11 | c.2553_2578del p.G852Tfs*100 (on ENST00000545668 / NM_152438.2; = p.K803Rfs*112 on NM_004399.3) | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, pindel
- EED | c.552_552+17del p.X184_splice | Splice Site (DEL) | VAF 8/14 reads (57%) | called by mutect2, varscan2
- FAM50A | c.574_576del p.E192del | In Frame Del (DEL) | VAF 9/56 reads (16%) | called by mutect2, pindel, varscan2
- JUP | c.1550dup p.L518Afs*93 | Frame Shift Ins (INS) | VAF 5/35 reads (14%) | called by mutect2, pindel, varscan2
- KARS1 | c.1012T>C p.C338R | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MYRF | c.2222_2224del p.K741del (on ENST00000278836 / NM_001127392.3; = p.K732del on NM_013279.4) | In Frame Del (DEL) | VAF 14/66 reads (21%) | called by pindel, varscan2
- RIMBP3 | c.2431G>A p.D811N | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- SGO1 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPATA31A1 | c.1753C>A p.L585M | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by mutect2, varscan2
- ACTR10 | c.1224G>A p.L408= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV99580995; called by muse, mutect2, varscan2
- ACTRT1 | c.435C>G p.L145= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV64419082, COSV64419263; called by muse, mutect2, varscan2
- ADAMTS10 | c.345G>A p.Q115= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV54354947; called by muse, varscan2
- ANKZF1 | c.1917G>A p.E639= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV99850363; called by muse, mutect2, varscan2
- BCAN | c.351C>T p.L117= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100227942, COSV61258849; called by muse, mutect2, varscan2
- BCAT1 | c.231G>A p.Q77= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as COSV99678301; called by muse, mutect2, varscan2
- BCL6 | c.33C>T p.F11= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs1223611602, COSV99215493; called by mutect2, varscan2
- C1orf43 | c.165C>A p.P55= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as COSV99670842; called by muse, mutect2, varscan2
- CAPN1 | c.1035C>T p.F345= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99658459; called by muse, mutect2, varscan2
- CARD10 | c.525G>A p.L175= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99324765; called by muse, mutect2, varscan2
- CELA1 | c.483G>A p.Q161= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs1168116255, COSV99530014; called by muse, mutect2, varscan2
- CHAD | c.375G>A p.L125= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs1404446302, COSV99366099; called by mutect2, varscan2
- COL2A1 | c.2394T>A p.G798= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV100475875; called by muse, mutect2, varscan2
- COL5A3 | c.1149G>A p.V383= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs773798103, COSV99318414; called by muse, mutect2, varscan2
- CPNE4 | c.264G>A p.V88= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV70190975, COSV70194771; called by muse, mutect2
- CTPS2 | c.525C>T p.F175= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as COSV100826737; called by muse, mutect2, varscan2
- CUL9 | c.2301C>T p.L767= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs773923193, COSV99335061; called by muse, varscan2
- CYSLTR1 | c.516G>A p.K172= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as rs1238767573, COSV100964711; called by muse, mutect2, varscan2
- DCX | c.597G>T p.L199= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV100576280; called by muse, mutect2, varscan2
- DGKD | c.756C>T p.C252= (on ENST00000264057 / NM_152879.3; = p.C208= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs764780242, COSV99895771; called by muse, mutect2, varscan2
- DICER1 | c.2005C>T p.L669= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV100601893; called by muse, mutect2, varscan2
- DIP2B | c.4488C>T p.F1496= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV99998156; called by muse, mutect2, varscan2
- DMGDH | c.1674C>T p.V558= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV54865621; called by muse, mutect2, varscan2
- EDAR | c.27G>A p.Q9= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV99303243; called by muse, mutect2, varscan2
- FAT4 | c.8760C>T p.F2920= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV100627759; called by muse, mutect2, varscan2
- FAXDC2 | c.378G>A p.V126= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV100394178; called by muse, varscan2
- FZD7 | c.1596C>T p.I532= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV99636974; called by muse, mutect2, varscan2
- GAK | c.3840G>A p.A1280= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs773959957, COSV58505509; called by muse, mutect2, varscan2
- GALNT17 | c.1797G>A p.*599= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as rs1281892111, COSV100352946; called by muse, mutect2, varscan2
- GJA5 | c.537G>A p.L179= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV99605418; called by muse, mutect2, varscan2
- GPR158 | c.678C>G p.L226= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV100893003; called by muse, mutect2, varscan2
- GPRIN1 | c.2919C>T p.T973= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1283132418; called by muse, mutect2
- GRK2 | c.573C>T p.F191= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100419599; called by muse, mutect2, varscan2
- HIF1A | c.1158C>G p.L386= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV60188865; called by muse, mutect2, varscan2
- HTT | c.3423C>G p.L1141= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100750562; called by muse, mutect2, varscan2
- IGF2R | c.1545C>T p.F515= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs1170675527, COSV100807192, COSV63632369; called by muse, mutect2, varscan2
- IGSF22 | c.825G>A p.L275= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV100079356; called by muse, mutect2, varscan2
- IKZF1 | c.1335G>A p.S445= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs1449766740, COSV100498146; called by muse, mutect2, varscan2
- INPP5J | c.1191C>T p.V397= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV100459235; called by muse, varscan2
- IRS2 | c.219C>G p.L73= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs1364090847, COSV101018905; called by muse, varscan2
- ITGA2 | c.420G>T p.G140= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV99670465; called by muse, mutect2, varscan2
- ITIH2 | c.306G>A p.Q102= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV100623222; called by muse, mutect2, varscan2
- ITIH5 | c.813G>A p.G271= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV99904086; called by muse, mutect2, varscan2
- ITPR2 | c.7599G>A p.L2533= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV101189882; called by muse, mutect2, varscan2
- JPH2 | c.888G>A p.K296= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100881653; called by muse, mutect2
- KDM4B | c.2667C>A p.L889= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99345884; called by muse, mutect2, varscan2
- KIAA1522 | c.1251C>T p.L417= (on ENST00000373480 / NM_001198972.2; = p.L476= on NM_020888.3) | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV53864735, COSV53865123; called by muse, mutect2, varscan2
- KIF26B | c.1641C>T p.H547= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs201431711; called by muse, mutect2, varscan2
- KMT2C | c.11622G>A p.E3874= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV51492905; called by muse, mutect2, varscan2
- KRT83 | c.405G>A p.Q135= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as COSV99531451; called by muse, mutect2, varscan2
- LRP8 | c.276C>T p.T92= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV100036211; called by muse, mutect2, varscan2
- LRRN4 | c.1110C>T p.L370= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs764857911, COSV101125390; called by muse, mutect2, varscan2
- LZTR1 | c.285C>T p.L95= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs932030455, COSV99301457; called by muse, mutect2, varscan2
- MAB21L4 | c.597C>T p.F199= (on ENST00000388934 / NM_001085437.3; = p.F31= on NM_024861.4) | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV56743547; called by muse, mutect2, varscan2
- MACF1 | c.11256C>T p.I3752= (on ENST00000372915; = p.I1685= on NM_012090.5) | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs760280713, COSV57127528; called by muse, mutect2, varscan2
- MAP3K9 | c.657C>A p.V219= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV101173521; called by muse, mutect2, varscan2
- MED1 | c.2022C>T p.G674= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV100327604; called by muse, mutect2, varscan2
- MLEC | c.450G>A p.V150= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs754913381, COSV99949599; called by muse, mutect2, varscan2
- MMP16 | c.1686G>A p.V562= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs757308005, COSV99686791; called by muse, mutect2, varscan2
- MORC1 | c.1276C>T p.L426= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV99225470; called by muse, mutect2, varscan2
- MYO7A | c.2184G>A p.L728= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as COSV101289081; called by muse, varscan2
- MYPN | c.105G>A p.A35= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs533632772, COSV62736662; called by muse, mutect2, varscan2
- MYPN | c.2235C>T p.F745= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs779158355, COSV100589712; called by muse, mutect2, varscan2
- NDUFA10 | c.852C>G p.L284= | Silent (SNP) | VAF 43/94 reads (46%) | catalogued as COSV99401287; called by muse, mutect2, varscan2
- NELFCD | c.1752G>A p.V584= (on ENST00000602795; = p.V566= on NM_198976.4) | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99413471; called by muse, mutect2
- NMT2 | c.1090C>T p.L364= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV100975494; called by muse, mutect2, varscan2
- OR1S1 | c.543C>T p.F181= | Silent (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- OR1S2 | c.543C>T p.F181= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs1266619981, COSV100224064; called by muse, varscan2
- OR6B3 | c.90C>G p.L30= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100097041; called by muse, mutect2, varscan2
- PCED1B | c.168C>T p.F56= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV71395017; called by muse, mutect2, varscan2
- PHC1 | c.2457C>T p.C819= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99134126; called by muse, mutect2
- PHF2 | c.279G>A p.L93= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs753481855, COSV100823073; called by muse, mutect2, varscan2
- PKM | c.1506C>T p.F502= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs771602110, COSV100064624; called by muse, mutect2, varscan2
- PLXND1 | c.5541G>T p.P1847= | Silent (SNP) | VAF 5/8 reads (63%) | catalogued as COSV60721058; called by muse, mutect2, varscan2
- PTPRB | c.1188G>A p.V396= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV99716390; called by muse, mutect2, varscan2
- RAB40C | c.543G>A p.E181= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs779670772, COSV99937612; called by muse, varscan2
- RAP2C | c.303C>T p.V101= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100747300; called by muse, mutect2, varscan2
- RNF165 | c.999C>T p.I333= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV99491420; called by muse, mutect2, varscan2
- RPUSD1 | c.498G>A p.L166= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99135655; called by muse, mutect2, varscan2
- SCN7A | c.432A>G p.R144= | Silent (SNP) | VAF 42/118 reads (36%) | catalogued as COSV101313134; called by muse, mutect2, varscan2
- SEMA4F | c.342G>A p.K114= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100335854; called by muse, varscan2
- SIPA1L2 | c.807G>A p.L269= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs746237929, COSV99477562; called by muse, mutect2, varscan2
- SLC32A1 | c.1536C>T p.L512= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs775676609, COSV99461962; called by muse, mutect2, varscan2
- SLC7A8 | c.1164C>T p.I388= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV100328296; called by muse, mutect2
- SLITRK2 | c.1620G>A p.L540= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV100157474, COSV59423889; called by muse, mutect2, varscan2
- SMG5 | c.2097C>T p.L699= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100700736; called by muse, mutect2, varscan2
- SPATA2L | c.357C>A p.L119= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV99232148; called by muse, mutect2, varscan2
- SREBF2 | c.1011C>A p.I337= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV100761363, COSV63331581; called by muse, mutect2, varscan2
- STEAP1 | c.69A>G p.E23= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV99787570; called by muse, mutect2, varscan2
- STRN4 | c.1069C>T p.L357= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV99623461; called by muse, mutect2, varscan2
- THOC6 | c.996G>C p.L332= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV99560475; called by muse, mutect2, varscan2
- TMEM141 | c.60C>T p.L20= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs751121447, COSV99264369; called by muse, mutect2, varscan2
- TMEM67 | c.48C>T p.L16= | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as COSV100018851; called by muse, mutect2, varscan2
- TRIM24 | c.915G>A p.V305= | Silent (SNP) | VAF 37/106 reads (35%) | catalogued as COSV100630758; called by muse, mutect2, varscan2
- UNC80 | c.708C>T p.I236= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99778838; called by muse, mutect2, varscan2
- ZCCHC8 | c.1293G>A p.Q431= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV60318963; called by muse, mutect2, varscan2
- ZCCHC8 | c.1185G>A p.Q395= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs781043571, COSV100288518; called by muse, mutect2, varscan2
- ZMAT1 | c.1916G>A p.*639= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV100858728; called by muse, mutect2, varscan2
- ZMYM2 | c.1059C>A p.L353= | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as COSV101243592; called by muse, mutect2, varscan2
- ZNF532 | c.1359C>T p.L453= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100266180; called by muse, mutect2, varscan2
- ZNF84 | c.243C>T p.V81= | Silent (SNP) | VAF 22/83 reads (27%) | called by muse, mutect2, varscan2
- PLEC | c.523+5523G>A | Intron (SNP) | VAF 9/24 reads (38%) | catalogued as COSV100512158, COSV59683956; called by muse, varscan2
- PTN | c.-199G>C | 5'UTR (SNP) | VAF 6/12 reads (50%) | catalogued as COSV100780811; called by muse, mutect2, varscan2
- RPL26P30 | n.814G>T | RNA (SNP) | VAF 18/33 reads (55%) | called by muse, mutect2, varscan2
- RPS2 | c.709+61C>G | Intron (SNP) | VAF 12/23 reads (52%) | catalogued as COSV99238741; called by muse, mutect2, varscan2
- Z83844.2 | c.1125-25G>A | Intron (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100379044; called by muse, mutect2, varscan2
- ZNF655 | c.136+1758G>A | Intron (SNP) | VAF 22/66 reads (33%) | catalogued as rs142834265; called by muse, mutect2, varscan2
- ZNF8 | c.*1G>A | 3'UTR (SNP) | VAF 17/40 reads (43%) | catalogued as COSV99544177; called by muse, mutect2, varscan2
